Somatic mutation profile of tumor specimen TCGA-QH-A6XC-01A (aliquot TCGA-QH-A6XC-01A-12D-A32B-08) from TCGA case TCGA-QH-A6XC, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.4 years (17,692 days).
Specimen TCGA-QH-A6XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07c3c73e-7624-42d1-b792-83a3a26cd74c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6XC-10B (Blood Derived Normal), aliquot TCGA-QH-A6XC-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2955fd71-de7c-40b4-b35a-7804e860678c

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Frame Shift Del 4, Nonsense Mutation 3, RNA 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 1322/1450 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- A1CF | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs773381488, COSV50979774; called by muse, mutect2, varscan2
- AGBL5 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100549101; called by muse, mutect2, varscan2
- AKAP9 | c.10777G>T p.G3593C (on ENST00000359028; = p.G3569C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV100662363; called by muse, mutect2, varscan2
- CA14 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV99354374; called by muse, mutect2, varscan2
- CACNA1G | c.4307G>A p.G1436E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661769; called by muse, mutect2, varscan2
- CLEC9A | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as rs754379977, COSV100191438; called by muse, mutect2, varscan2
- CLIC3 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1186813837, COSV100860394; called by mutect2, varscan2
- DCC | c.3809G>A p.C1270Y | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV71439865; called by muse, mutect2, varscan2
- DNAH2 | c.9559G>A p.G3187S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs200910918, COSV101209291; called by muse, mutect2, varscan2
- DSC3 | c.943-1G>A p.X315_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100844595; called by muse, mutect2, varscan2
- FAM214B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100521304; called by muse, mutect2, varscan2
- GLS2 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100358349; called by muse, mutect2, varscan2
- HERC1 | c.6934G>T p.G2312* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV101496553; called by muse, mutect2, varscan2
- JTB | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55131923; called by muse, mutect2, varscan2
- KEL | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 73/456 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs907281808, COSV62335758; called by muse, mutect2, varscan2
- LAMA1 | c.5586G>T p.R1862S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV101056320; called by muse, mutect2, varscan2
- LRBA | c.7702C>A p.P2568T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100841510; called by muse, mutect2, varscan2
- LRFN2 | c.2306G>T p.S769I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV100599545; called by muse, mutect2, varscan2
- LUZP2 | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100419835; called by muse, mutect2, varscan2
- LY75 | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs374255543, COSV99716432; called by muse, mutect2, varscan2
- MEI1 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.14); catalogued as rs1389753330, COSV100299939; called by muse, mutect2, varscan2
- MYH13 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs373641414; called by muse, mutect2, varscan2
- RELN | c.8864G>A p.R2955H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV59036044; called by muse, mutect2, varscan2
- RELN | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs145135688; ClinVar: uncertain significance; called by muse, varscan2
- ROS1 | c.6116G>A p.R2039H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs3752566; called by muse, mutect2, varscan2
- SEMA4A | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV100740577; called by muse, mutect2, varscan2
- SLC35F3 | c.640G>A p.A214T (on ENST00000366617 / NM_001300845.1; = p.A283T on NM_173508.4) | Missense Mutation (SNP) | VAF 176/420 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762720695, COSV100784683; called by muse, mutect2, varscan2
- TBC1D22A | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV100453054; called by muse, mutect2, varscan2
- TIE1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs150406982; called by muse, mutect2, varscan2
- TRAT1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as rs148894492; called by muse, mutect2, varscan2
- TRDV1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs575717965, COSV101153525; called by muse, mutect2, varscan2
- UNC5A | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs149355192; called by muse, varscan2
- ZBTB11 | c.2914A>C p.M972L | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100465450; called by muse, mutect2, varscan2
- C2orf69 | c.568_580del p.V192Ifs*2 | Frame Shift Del (DEL) | VAF 27/53 reads (51%) | called by mutect2, pindel, varscan2
- MTMR2 | c.1629_1630del p.I544Kfs*9 | Frame Shift Del (DEL) | VAF 43/125 reads (34%) | called by mutect2, pindel, varscan2
- SETD9 | c.482_483del p.K161Ifs*2 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- STXBP4 | c.1188+2_1188+5del p.X396_splice | Splice Site (DEL) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- ZNF594 | c.2204_2205del p.L735Rfs*4 | Frame Shift Del (DEL) | VAF 82/253 reads (32%) | called by mutect2, pindel, varscan2
- COL1A2 | c.789C>T p.P263= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV51961070; called by muse, mutect2, varscan2
- EQTN | c.873G>A p.S291= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as COSV66219107; called by muse, mutect2, varscan2
- GAS7 | c.987C>T p.L329= (on ENST00000432992 / NM_201433.2; = p.L189= on NM_003644.3) | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs769901833, COSV100095429, COSV60443749; called by muse, mutect2, varscan2
- KIF20B | c.2163A>G p.K721= (on ENST00000371728 / NM_001284259.2; = p.K681= on NM_016195.4) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99590002; called by muse, mutect2
- KLK5 | c.279C>T p.C93= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs201029495, COSV60450368; called by muse, mutect2, varscan2
- MKRN1 | c.1302C>T p.N434= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs147839699; called by muse, mutect2, varscan2
- NID2 | c.141C>G p.L47= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV99356511; called by muse, mutect2, varscan2
- PLCXD1 | c.642G>A p.L214= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV101087863; called by muse, mutect2, varscan2
- PRR27 | c.222G>A p.S74= | Silent (SNP) | VAF 63/170 reads (37%) | catalogued as rs971810835, COSV100748805; called by muse, mutect2, varscan2
- PRSS55 | c.381C>T p.N127= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs771081101, COSV60808364; called by muse, mutect2, varscan2
- PSG7 | c.519T>C p.T173= | Silent (SNP) | VAF 102/338 reads (30%) | catalogued as COSV101343238; called by muse, mutect2, varscan2
- TRPM6 | c.2082G>A p.L694= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs570964806, COSV100666306; called by muse, mutect2, varscan2
- USP29 | c.2529C>T p.S843= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs776535799, COSV54141536; called by muse, mutect2, varscan2
- DCHS2 | n.5555C>T | RNA (SNP) | VAF 19/45 reads (42%) | catalogued as rs774862535, COSV100601746; called by muse, mutect2, varscan2
- MIR543 | n.56C>T | RNA (SNP) | VAF 19/49 reads (39%) | catalogued as rs760890689; called by muse, mutect2, varscan2
